Somatic mutation profile of tumor specimen TCGA-30-1856-01A (aliquot TCGA-30-1856-01A-01W-0639-09) from TCGA case TCGA-30-1856, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.5 years (20,626 days).
Specimen TCGA-30-1856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3bd58a29-bfb6-4e60-8d1b-d7de89b12cff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1856-10A (Blood Derived Normal), aliquot TCGA-30-1856-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cde968e-6629-4a6f-8dbe-a2bb371d7292

The open-access MAF lists 67 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 48, Silent 12, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 66/123 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ABCA8 | c.4409G>C p.G1470A | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52201433; called by muse, mutect2, varscan2
- AIPL1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs1049797491, COSV51507102; called by muse, mutect2, varscan2
- ALMS1 | c.4940C>T p.A1647V | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100042854; called by muse, mutect2
- ATP4A | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs773824281, COSV52868097; called by muse, mutect2, varscan2
- AZIN2 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53857534; called by muse, mutect2, varscan2
- BAZ2B | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58600975; called by muse, mutect2, varscan2
- C11orf68 | c.559G>T p.E187* (on ENST00000530188; = p.E228* on NM_031450.4) | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100437119; called by muse, mutect2, varscan2
- C1orf174 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV64365829; called by muse, mutect2, varscan2
- CACNA1I | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV60808445; called by muse, mutect2, varscan2
- CBLL2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 78/420 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs371087148, COSV60369056; called by muse, mutect2, varscan2
- CCDC158 | c.2509T>A p.L837I | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV66356003; called by muse, mutect2, varscan2
- CHN1 | c.537del p.S180Qfs*5 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | catalogued as COSV69296468; called by mutect2, varscan2
- CNTNAP2 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs751589771, COSV62182713; called by muse, mutect2, varscan2
- COL11A1 | c.1308+1G>T p.X436_splice | Splice Site (SNP) | VAF 8/176 reads (5%) | catalogued as COSV62173187; called by muse, mutect2
- CRY2 | c.709C>G p.L237V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV101314599; called by muse, mutect2, varscan2
- CSTF2T | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100484246; called by muse, mutect2
- CYP7B1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs775898739, COSV59588504; called by muse, mutect2, varscan2
- DDI2 | c.170A>G p.N57S | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as rs1384277523, COSV60779765; called by muse, mutect2, varscan2
- DOP1B | c.2060del p.I687Tfs*108 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | catalogued as COSV67693420, COSV67693904; called by mutect2, pindel, varscan2
- ELP4 | c.65G>C p.S22T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.096); catalogued as COSV53444305; called by muse, mutect2, varscan2
- ENPP2 | c.294C>A p.A98= | Splice Region (SNP) | VAF 29/205 reads (14%) | catalogued as COSV50014927; called by muse, mutect2, varscan2
- ETV1 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.869); catalogued as rs767552829, COSV54137083; called by muse, mutect2, varscan2
- GYS2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 78/556 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762150312, COSV53920433; called by muse, mutect2, varscan2
- H2AC17 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100377647; called by muse, mutect2
- H3C3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV100778302; called by muse, mutect2, varscan2
- ITGA8 | c.826T>C p.F276L | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV65228987, COSV65229100; called by muse, mutect2, varscan2
- KCNQ5 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59660302; called by muse, mutect2, varscan2
- KCNU1 | c.2971G>T p.D991Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101298899, COSV67755911; called by muse, mutect2, varscan2
- LHX9 | c.362A>G p.K121R | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.629); catalogued as COSV61328807; called by muse, mutect2, varscan2
- MBNL1 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 77/540 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.054); catalogued as rs780538995, COSV56828467, COSV56836247; called by muse, mutect2, varscan2
- MMP24 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs557891491, COSV55770142; called by muse, mutect2, varscan2
- MYH15 | c.2674C>T p.L892F | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV56310061; called by muse, mutect2, varscan2
- MYO3A | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 154/263 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0.346); catalogued as COSV56331236; called by muse, mutect2, varscan2
- NBPF15 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 170/1292 reads (13%) | catalogued as COSV64992945; called by muse, mutect2, varscan2
- NRXN2 | c.3323A>C p.Q1108P | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV55453403; called by muse, mutect2, varscan2
- PADI2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs750267958, COSV64945874; called by muse, mutect2, varscan2
- PDLIM4 | c.407del p.P136Hfs*24 | Frame Shift Del (DEL) | VAF 27/117 reads (23%) | catalogued as COSV53804425; called by mutect2, pindel, varscan2
- PECR | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as rs1306313346, COSV54734398; called by muse, mutect2, varscan2
- PGAP1 | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV61326227; called by muse, mutect2, varscan2
- PLD3 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1363625764, COSV100735215; called by muse, mutect2, varscan2
- RASGRF1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753280280, COSV69179038; called by muse, mutect2, varscan2
- RPS6KC1 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 40/293 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV65299380; called by muse, mutect2, varscan2
- SERPINA4 | c.1187T>A p.I396N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV54069962; called by muse, mutect2, varscan2
- SERPINB8 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV54639597; called by muse, mutect2, varscan2
- SKOR1 | c.2749A>G p.N917D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV58246012; called by muse, mutect2, varscan2
- SOSTDC1 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61049288; called by muse, mutect2, varscan2
- SPAM1 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1210086667, COSV56143841; called by muse, mutect2, varscan2
- TASOR2 | c.6041C>G p.S2014C | Missense Mutation (SNP) | VAF 166/298 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV60167509; called by muse, varscan2
- THSD7B | c.3902C>G p.T1301S (on ENST00000272643; = p.T1299S on NM_001316349.2) | Missense Mutation (SNP) | VAF 55/257 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV55687791; called by muse, mutect2, varscan2
- TTN | c.40324C>T p.R13442W (on ENST00000591111; = p.R6018W on NM_003319.4) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | PolyPhen probably damaging (0.977); catalogued as rs199834143, COSV59993118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA1C | c.1290G>T p.K430N | Missense Mutation (SNP) | VAF 8/217 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99988842; called by muse, mutect2
- ZNF251 | c.1376A>G p.K459R | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.306); catalogued as rs769614747, COSV52957420; called by muse, mutect2, varscan2
- ZNF792 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.61); catalogued as COSV101289716; called by muse, varscan2
- ABTB1 | c.912C>G p.H304Q (on ENST00000232744 / NM_172027.3; = p.H162Q on NM_032548.3) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DDX17 | c.1611G>A p.L537= | Silent (SNP) | VAF 38/211 reads (18%) | catalogued as COSV53247731; called by muse, mutect2, varscan2
- DIS3 | c.1662C>T p.D554= | Silent (SNP) | VAF 36/185 reads (19%) | catalogued as rs761298713, COSV66706452, COSV66706455; called by muse, varscan2
- H3C3 | c.27C>T p.R9= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as rs752104215, COSV100778226, COSV100778303; called by muse, mutect2, varscan2
- HCK | c.405C>T p.R135= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as rs913095249, COSV52941773; called by muse, mutect2
- HECW1 | c.1476G>A p.T492= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1186992883, COSV67822537; called by muse, mutect2, varscan2
- LARGE1 | c.1662C>T p.I554= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV61661978; called by muse, mutect2, varscan2
- MIOX | c.204C>T p.Y68= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99326961; called by muse, mutect2
- MYLK2 | c.1632G>A p.A544= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs772321212, COSV65659070; ClinVar: likely benign; called by muse, mutect2, varscan2
- OBSCN | c.10368G>A p.L3456= | Silent (SNP) | VAF 16/125 reads (13%) | catalogued as rs998266340, COSV52774567; called by muse, mutect2, varscan2
- STAT1 | c.135C>T p.H45= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as rs566696388, COSV63117126, COSV63117893; called by muse, mutect2, varscan2
- TYR | c.1479A>G p.A493= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV54475682; called by muse, mutect2, varscan2
- ZNF43 | c.1407T>C p.L469= | Silent (SNP) | VAF 79/672 reads (12%) | catalogued as COSV61684017; called by muse, mutect2, varscan2
